Somatic mutation profile of tumor specimen MP2PRT-PAUMUM-TMP1-A (aliquot MP2PRT-PAUMUM-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAUMUM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.7 years (3,172 days).
Specimen MP2PRT-PAUMUM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aceffa38-5395-4506-bd07-5ab82c7e62d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUMUM-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUMUM-NM1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/432cd3af-8fb4-41ee-9697-94a7afbcf68e

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDOB | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 79/221 reads (36%) | catalogued as rs118204428, CM950061; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 252/392 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DNAH9 | c.6517C>T p.R2173W | Missense Mutation (SNP) | VAF 93/351 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs774222974, COSV52340595; called by muse, mutect2, varscan2
- ITGA6 | c.1897C>A p.R633S (on ENST00000442250; = p.R594S on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/376 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51219244; called by muse, mutect2, varscan2
- PAX5 | c.239C>G p.P80R | Missense Mutation (SNP) | VAF 178/217 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63905332; called by muse, mutect2, varscan2
- HAPLN1 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 86/246 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PPP2R3B | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 110/441 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
